Somatic mutation profile of tumor specimen MMRF_2251_1_BM_CD138pos (aliquot MMRF_2251_1_BM_CD138pos_T2_KHS5U_K14059) from MMRF case MMRF_2251, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.1 years (17,192 days).
Specimen MMRF_2251_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c73aee6-bb22-4401-8706-bb728ea9bcfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2251_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2251_1_PB_CD3pos_C1_KHS5U_K14058; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52ad6757-745a-4fb4-b6ce-f6aa5cf54aaf

The open-access MAF lists 117 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 30, Intron 16, Silent 14, 5'UTR 7, RNA 2, 3'Flank 2, 5'Flank 2, Splice Site 1, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 61/71 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753836442; called by muse, mutect2, varscan2
- ADGRG6 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204304460; called by muse, mutect2, varscan2
- AHI1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 239/421 reads (57%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV55630224; called by muse, mutect2, varscan2
- AP1G2 | c.2333A>G p.N778S | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1268177265; called by muse, mutect2, varscan2
- GJA5 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 171/344 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV54783847; called by muse, mutect2, varscan2
- HMCN1 | c.2450A>G p.Q817R | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.759); catalogued as COSV54931341; called by muse, mutect2, varscan2
- IGHV2-70D | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 55/55 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1457244699; called by muse, varscan2
- IGLV3-1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.175); catalogued as rs557374670; called by muse, mutect2, varscan2
- KCTD8 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs574038147, COSV100759519; called by muse, mutect2, varscan2
- MCM10 | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 209/433 reads (48%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs141967915, COSV66333131; called by muse, mutect2, varscan2
- MRGPRX3 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.944); catalogued as rs747757094, COSV101283560; called by muse, mutect2, varscan2
- OTUB1 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs146537845; called by muse, mutect2, varscan2
- PCDHA13 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs200846533, COSV56547954; called by muse, mutect2
- SLC6A17 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs142828529; called by muse, mutect2, varscan2
- TNKS | c.2812A>G p.T938A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs373055237; called by muse, mutect2, varscan2
- TYRP1 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 98/243 reads (40%) | catalogued as rs371562555; called by muse, mutect2, varscan2
- UBL4A | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 114/220 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54835991; called by muse, mutect2, varscan2
- UGT2B15 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV57736891; called by muse, mutect2, varscan2
- ZNF510 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1166268677; called by muse, mutect2, varscan2
- ADAM29 | c.682A>T p.I228F | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- APOL1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- BCL9L | c.3388C>T p.P1130S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2
- CKAP2 | c.757G>T p.V253L (on ENST00000378037 / NM_001098525.2; = p.V252L on NM_018204.5) | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CROCC2 | c.4631C>T p.S1544F | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CRPPA | c.1118C>T p.S373L (on ENST00000407010 / NM_001368197.1; = p.S323L on NM_001101417.4) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DENND4C | c.5673A>C p.Q1891H (on ENST00000434457 / NM_001330640.2; = p.Q1842H on NM_017925.7) | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); called by muse, mutect2
- FREM1 | c.5351C>A p.A1784D | Missense Mutation (SNP) | VAF 142/347 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA6L7 | c.5T>A p.M2K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- H2BC21 | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- IGHV2-70D | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 55/55 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, varscan2
- INTS6 | c.866T>C p.F289S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- MFGE8 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MUC5B | c.8834G>A p.R2945K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.113); called by muse, mutect2
- OR10H3 | c.931T>G p.F311V | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- PRAG1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PRAME | c.1275T>G p.S425R | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2
- PURA | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SHISA4 | c.379+2T>C p.X127_splice | Splice Site (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- SLC49A4 | c.1160T>A p.I387N | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TCERG1L | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TP73 | c.737G>C p.G246A | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- WBP1L | c.610G>C p.G204R | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ZNF708 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2
- ADCY2 | c.2856C>T p.S952= | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as rs375968791, COSV57860831; called by muse, mutect2, varscan2
- BBX | c.1998G>C p.G666= | Silent (SNP) | VAF 84/162 reads (52%) | called by muse, mutect2, varscan2
- CYP1A1 | c.1446G>A p.V482= | Silent (SNP) | VAF 92/191 reads (48%) | called by muse, mutect2, varscan2
- HNRNPH2 | c.12C>T p.S4= | Silent (SNP) | VAF 226/502 reads (45%) | called by muse, mutect2, varscan2
- HPS4 | c.615C>T p.L205= | Silent (SNP) | VAF 81/166 reads (49%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.1785C>G p.T595= | Silent (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- INPP5K | c.330C>T p.I110= | Silent (SNP) | VAF 116/151 reads (77%) | called by muse, mutect2, varscan2
- INSC | c.1257C>T p.L419= | Silent (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- LPAR6 | c.948C>T p.F316= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV57303361, COSV57307458, COSV99926504; called by muse, mutect2, varscan2
- MEGF9 | c.1560C>T p.V520= | Silent (SNP) | VAF 101/236 reads (43%) | called by muse, mutect2, varscan2
- NYAP1 | c.1491G>A p.G497= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV55717681; called by muse, mutect2, varscan2
- PRKCG | c.15C>A p.G5= | Silent (SNP) | VAF 180/385 reads (47%) | catalogued as COSV99668558; called by muse, mutect2, varscan2
- SPTB | c.5148G>A p.P1716= | Silent (SNP) | VAF 107/199 reads (54%) | catalogued as rs539974597, COSV67630611, COSV67630697; called by muse, mutect2, varscan2
- ZBTB46 | c.876C>T p.A292= | Silent (SNP) | VAF 105/195 reads (54%) | catalogued as rs1469606162; called by muse, mutect2, varscan2
- AC103564.2 | n.1022G>A | RNA (SNP) | VAF 32/73 reads (44%) | catalogued as rs1449107450; called by muse, mutect2, varscan2
- ADAM33 | c.1133+211G>A | Intron (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2
- AQP12A | c.-1G>A | 5'UTR (SNP) | VAF 67/141 reads (48%) | catalogued as rs145786292; called by muse, mutect2, varscan2
- ARHGAP6 | c.*409A>G | 3'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- ATF4 | c.-699A>G | 5'UTR (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- C21orf91 | c.*3106A>T | 3'UTR (SNP) | VAF 54/128 reads (42%) | called by muse, mutect2, varscan2
- CHRM3 | c.*3019G>A | 3'UTR (SNP) | VAF 66/139 reads (47%) | called by muse, mutect2, varscan2
- CMC1 | c.19+37C>T | Intron (SNP) | VAF 39/90 reads (43%) | catalogued as rs1465358866, COSV58362375; called by muse, mutect2, varscan2
- COBLL1 | c.1110+80C>G | Intron (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2
- CRISP3 | chr6:49727518 T>G | 3'Flank (SNP) | VAF 69/112 reads (62%) | called by muse, mutect2, varscan2
- CSMD1 | c.*437A>G | 3'UTR (SNP) | VAF 54/84 reads (64%) | called by muse, mutect2, varscan2
- DIAPH2 | c.*5287T>G | 3'UTR (SNP) | VAF 64/142 reads (45%) | called by muse, varscan2
- DIPK2A | c.*579T>G | 3'UTR (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- DOLK | c.-234C>T | 5'UTR (SNP) | VAF 75/207 reads (36%) | called by muse, mutect2, varscan2
- ECI2 | c.50+314G>A | Intron (SNP) | VAF 49/104 reads (47%) | called by muse, mutect2, varscan2
- EIF4E3 | c.*470A>C | 3'UTR (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- ELP1 | c.*1513T>C | 3'UTR (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- EN1 | c.-450C>G | 5'UTR (SNP) | VAF 7/16 reads (44%) | catalogued as rs1399129224; called by muse, mutect2, varscan2
- ETS2 | c.*386T>C | 3'UTR (SNP) | VAF 91/148 reads (61%) | called by muse, mutect2, varscan2
- GARS1 | c.1903+59G>A | Intron (SNP) | VAF 38/76 reads (50%) | catalogued as rs1334091507; called by muse, mutect2, varscan2
- GPR153 | c.*1011C>T | 3'UTR (SNP) | VAF 41/82 reads (50%) | catalogued as rs768216586; called by muse, mutect2, varscan2
- GPS1 | chr17:82051234 C>T | 5'Flank (SNP) | VAF 21/48 reads (44%) | catalogued as rs1158795203; called by muse, mutect2, varscan2
- H4C9 | c.*147T>G | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- HS2ST1 | c.*132_*135del | 3'UTR (DEL) | VAF 24/84 reads (29%) | catalogued as rs1450381150; called by pindel, varscan2
- IL1RAP | chr3:190656437 C>T | 3'Flank (SNP) | VAF 142/317 reads (45%) | called by muse, mutect2, varscan2
- IL7R | c.*2853A>G | 3'UTR (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- KANK1 | c.3333+924C>T | Intron (SNP) | VAF 9/22 reads (41%) | catalogued as rs188538580; called by muse, varscan2
- KCNJ12 | c.*195G>A | 3'UTR (SNP) | VAF 33/79 reads (42%) | catalogued as rs546339922, COSV100054747; called by muse, mutect2, varscan2
- LCLAT1 | c.*2579C>G | 3'UTR (SNP) | VAF 14/81 reads (17%) | catalogued as rs1376011107; called by mutect2, varscan2
- LIG3 | c.*3195G>A | 3'UTR (SNP) | VAF 48/99 reads (48%) | called by muse, mutect2
- LMF1 | c.1417-244C>T | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- LRPAP1 | c.*5851G>A | 3'UTR (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- MBNL3 | c.-12T>G | 5'UTR (SNP) | VAF 177/393 reads (45%) | called by muse, mutect2, varscan2
- MGAT5 | c.*4321T>C | 3'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- MIR548G | n.3T>G | RNA (SNP) | VAF 84/179 reads (47%) | called by muse, mutect2, varscan2
- MSL3 | c.908+37C>T | Intron (SNP) | VAF 23/56 reads (41%) | catalogued as rs754751311; called by muse, mutect2, varscan2
- NEIL1 | c.-23+500C>T | Intron (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- OGDH | c.1206+22G>A | Intron (SNP) | VAF 96/196 reads (49%) | catalogued as rs1302690111; called by muse, mutect2, varscan2
- OR56A1 | c.*129A>T | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- PCDH11X | c.*1333T>C | 3'UTR (SNP) | VAF 182/351 reads (52%) | called by muse, mutect2, varscan2
- PCDH19 | c.*3708G>C | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- PCDH19 | c.-301G>T | 5'UTR (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2
- PRDX4 | chrX:23664648 A>T | 5'Flank (SNP) | VAF 66/81 reads (81%) | called by muse, mutect2, varscan2
- RADX | c.*1043G>A | 3'UTR (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- RTN2 | c.1556+64C>T | Intron (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- SAP18 | c.*853G>T | 3'UTR (SNP) | VAF 50/88 reads (57%) | called by muse, mutect2, varscan2
- SEMA5A | c.*2676C>A | 3'UTR (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- SERINC4 | c.*661G>T | 3'UTR (SNP) | VAF 225/493 reads (46%) | called by muse, mutect2, varscan2
- SGK1 | c.152+78A>G | Intron (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2
- SMAD9 | c.*930G>A | 3'UTR (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- SNTN | c.*495del | 3'UTR (DEL) | VAF 45/110 reads (41%) | called by mutect2, pindel, varscan2
- SYTL4 | c.1006-447T>G | Intron (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- TP63 | c.1350-5112C>G | Intron (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- TRPC5 | c.*1524T>G | 3'UTR (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- UNC93B1 | c.-37C>T | 5'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- VGLL3 | c.937+6515A>G | Intron (SNP) | VAF 39/98 reads (40%) | catalogued as rs912214802; called by muse, mutect2, varscan2
- WAC | c.*536C>T | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- ZDBF2 | c.*2621T>C | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- ZNF717 | c.184+51A>C | Intron (SNP) | VAF 76/150 reads (51%) | called by muse, mutect2, varscan2
